TCGA case TCGA-AR-A1AR — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eda6d2d5-4199-4f76-a45b-1d0401b4e54c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 524 days (1.4 years).

Diagnoses (4)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 50.6 years (18,482 days); Year of diagnosis: 2007; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Lower Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 14.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Days to treatment end: 159 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment end: 159 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant; Days to treatment end: 159 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment end: 251 days; Course number: 1.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Upper limb, NOS; Laterality: Left; Classification of tumor: Prior primary; AJCC pathologic stage: Stage III.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 51.3 years (18,750 days); Days to diagnosis: 268 days; Prior treatment: Yes.
4. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 51.7 years (18,869 days); Days to diagnosis: 387 days (1.1 years); Prior treatment: Yes.

Follow-up (2 entries)
- Days to follow up: 524 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 524 days (1.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): Negative.
- PGR (IHC): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A1AR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-AR-A1AR-01A-03-TSC: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AR-A1AR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A1AR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Lower Inner Quadrant.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes; New tumor event type: New Primary Tumor.
- Drug treatment 1: Regimen number: 1.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Shoulder; Other malignancy histological type: Malignant Melanoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -6213.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 524 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 524 days; disease-free interval: event (new tumor event after initially disease-free), 268 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 268 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A1AR-01A-31D-A134-01): tumor purity 0.54, ploidy 1.78, whole-genome doublings 0.
